Somatic mutation profile of tumor specimen TCGA-CQ-6219-01A (aliquot TCGA-CQ-6219-01A-11D-1912-08) from TCGA case TCGA-CQ-6219, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 50.9 years (18,578 days).
Specimen TCGA-CQ-6219-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6faddaee-5d96-4812-a01e-9f3eb38e43c8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CQ-6219-10A (Blood Derived Normal), aliquot TCGA-CQ-6219-10A-01D-1912-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4cc8d95b-ac27-46bc-b32f-7d6b9a29d211

The open-access MAF lists 61 somatic variants for this specimen: 46 protein-altering or splice-affecting, 15 silent.
By variant classification: Missense Mutation 40, Silent 15, Nonsense Mutation 5, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 10/70 reads (14%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2
- TP53 | c.638G>C p.R213P | Missense Mutation (SNP) | VAF 11/42 reads (26%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- ABHD10 | c.693dup p.H232Tfs*2 | Frame Shift Ins (INS) | VAF 19/136 reads (14%) | catalogued as rs777310247; called by mutect2, pindel, varscan2
- ARHGAP30 | c.3130C>T p.P1044S (on ENST00000368013 / NM_001025598.2; = p.P833S on NM_181720.3) | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); catalogued as COSV100920147; called by muse, varscan2
- AVPR2 | c.1049G>C p.S350T | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.047); catalogued as COSV100509427; called by muse, mutect2
- BPTF | c.2558A>G p.N853S | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100074214; called by muse, mutect2
- CENPE | c.2013A>T p.L671F | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as COSV99477122; called by muse, mutect2, varscan2
- COG3 | c.1397A>T p.Y466F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.092); catalogued as COSV100596391; called by muse, mutect2, varscan2
- DAB2IP | c.829C>T p.R277W (on ENST00000408936; = p.R249W on NM_032552.3) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as rs1428145625, COSV99404815; called by muse, mutect2, varscan2
- DHX36 | c.715C>T p.Q239* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100273361, COSV57675817; called by muse, mutect2
- DLGAP1 | c.550A>C p.S184R | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV100228287; called by muse, mutect2
- DNAH11 | c.5429G>A p.R1810K | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs767520808, COSV100177523; called by muse, mutect2
- EYS | c.1652G>A p.R551Q | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs773906269, COSV100676414, COSV60994595; called by muse, mutect2, varscan2
- H4-16 | c.206A>G p.D69G | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); catalogued as COSV100797616; called by muse, mutect2, varscan2
- HOXB2 | c.104C>T p.S35L | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100344473; called by muse, mutect2, varscan2
- HSP90AB1 | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as COSV100806959; called by muse, mutect2, varscan2
- HSP90AB1 | c.2033A>T p.N678I | Missense Mutation (SNP) | VAF 40/390 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.482); catalogued as COSV99240924; called by muse, mutect2, varscan2
- KCNJ2 | c.1099A>G p.I367V | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT tolerated (0.31); PolyPhen benign (0.145); catalogued as COSV99696222; called by muse, mutect2, varscan2
- LGALS9C | c.992A>G p.Y331C | Missense Mutation (SNP) | VAF 20/132 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.019); catalogued as COSV100055507; called by muse, mutect2
- MALT1 | c.1285G>A p.D429N | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.363); catalogued as COSV100618599; called by muse, mutect2
- MED1 | c.1415C>G p.S472* | Nonsense Mutation (SNP) | VAF 24/350 reads (7%) | catalogued as COSV56127722; called by muse, mutect2
- MEFV | c.1839C>G p.F613L | Missense Mutation (SNP) | VAF 45/357 reads (13%) | SIFT tolerated (0.62); PolyPhen benign (0.106); catalogued as COSV99560333, COSV99560658; called by muse, mutect2, varscan2
- MICAL2 | c.3845C>T p.S1282L | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.706); catalogued as COSV99811470; called by muse, mutect2, varscan2
- MOCS2 | c.139A>G p.I47V | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.177); catalogued as COSV63740933; called by muse, mutect2
- MRI1 | c.746G>A p.R249H (on ENST00000040663 / NM_001031727.4; = p.R202H on NM_032285.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777122398, COSV99237247; called by muse, mutect2, varscan2
- MYCL | c.248G>T p.G83V (on ENST00000372816 / NM_001033081.3; = p.G113V on NM_005376.5) | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.3); PolyPhen benign (0.265); catalogued as COSV100862300; called by muse, mutect2, varscan2
- NOTCH1 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750215904, COSV53058129, COSV53074787; called by muse, mutect2, varscan2
- PABPC4 | c.472A>G p.M158V | Missense Mutation (SNP) | VAF 21/202 reads (10%) | SIFT tolerated (0.79); PolyPhen benign (0.276); catalogued as COSV100790854; called by muse, mutect2, varscan2
- PAK5 | c.2111G>T p.G704V | Missense Mutation (SNP) | VAF 24/225 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as COSV100781137; called by muse, mutect2, varscan2
- PCDH11X | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.9); catalogued as COSV100011420; called by muse, mutect2, varscan2
- PFKL | c.1688A>G p.K563R | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.39); PolyPhen benign (0.088); catalogued as COSV100346044; called by muse, mutect2, varscan2
- PHF20L1 | c.877G>C p.D293H | Missense Mutation (SNP) | VAF 34/131 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV99620437; called by muse, mutect2, varscan2
- PLCL1 | c.495G>T p.E165D | Missense Mutation (SNP) | VAF 24/91 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1297667404, COSV101406806, COSV70846424; called by muse, mutect2, varscan2
- POLQ | c.5519T>A p.F1840Y | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99951697; called by muse, mutect2, varscan2
- RBL1 | c.730G>C p.E244Q | Missense Mutation (SNP) | VAF 7/168 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV100726893; called by muse, mutect2
- RNF157 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53947384; called by muse, mutect2
- RPA1 | c.958A>G p.I320V | Missense Mutation (SNP) | VAF 54/149 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.116); catalogued as rs777886740, COSV99627716; called by muse, mutect2, varscan2
- RPGRIP1 | c.2761G>A p.V921M | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV99250531; called by muse, mutect2, varscan2
- SIDT2 | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.02); catalogued as COSV54054876; called by muse, mutect2, varscan2
- TM9SF4 | c.174C>G p.Y58* | Nonsense Mutation (SNP) | VAF 14/87 reads (16%) | catalogued as COSV54106894, COSV99454011; called by muse, mutect2, varscan2
- TRIP12 | c.4859A>T p.Y1620F | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.899); catalogued as COSV99389468; called by muse, mutect2
- TTBK1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 8/95 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs1204751802, COSV52494343, COSV99445456; called by muse, mutect2
- VPS52 | c.313G>C p.E105Q | Missense Mutation (SNP) | VAF 7/101 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.336); catalogued as COSV101460408; called by muse, mutect2
- WDFY3 | c.4267G>T p.D1423Y | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99882277; called by muse, mutect2, varscan2
- WNK3 | c.1255G>C p.D419H | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100670638; called by muse, mutect2, varscan2
- ITGAX | c.1211dup p.Y404* | Nonsense Mutation (INS) | VAF 13/107 reads (12%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.4656A>T p.G1552= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV100040831; called by muse, mutect2, varscan2
- CASP4 | c.445C>T p.L149= | Silent (SNP) | VAF 6/98 reads (6%) | called by muse, mutect2
- CCDC130 | c.1062G>C p.G354= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV99237245; called by muse, mutect2, varscan2
- COL15A1 | c.417G>A p.T139= | Silent (SNP) | VAF 30/123 reads (24%) | catalogued as COSV66641534; called by muse, mutect2, varscan2
- COPA | c.1314G>A p.K438= | Silent (SNP) | VAF 8/71 reads (11%) | catalogued as COSV99614744; called by muse, mutect2, varscan2
- DMD | c.7462C>T p.L2488= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV100626093; called by muse, mutect2, varscan2
- GGT7 | c.330C>T p.I110= | Silent (SNP) | VAF 9/94 reads (10%) | catalogued as rs758677980, COSV60540192; called by muse, mutect2, varscan2
- LGI2 | c.1005C>T p.D335= | Silent (SNP) | VAF 14/99 reads (14%) | catalogued as rs770238612, COSV101180773; called by muse, mutect2, varscan2
- MRPS33 | c.210C>G p.L70= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV100244662; called by muse, mutect2, varscan2
- NBAS | c.6102G>A p.K2034= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as COSV99867585; called by muse, mutect2
- PAX3 | c.1272G>A p.T424= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as rs746069520, COSV100399128, COSV60593022; called by muse, mutect2, varscan2
- PSMD2 | c.2286G>A p.V762= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs1371945136, COSV100031567; called by muse, mutect2, varscan2
- RIF1 | c.3651G>A p.R1217= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV99690155; called by muse, mutect2, varscan2
- THSD7A | c.753C>G p.L251= | Silent (SNP) | VAF 15/70 reads (21%) | catalogued as rs1300373333, COSV101448559; called by muse, mutect2, varscan2
- TSPAN14 | c.126C>T p.S42= | Silent (SNP) | VAF 19/116 reads (16%) | catalogued as rs757374758, COSV100540163; called by muse, mutect2, varscan2
